Somatic mutation profile of tumor specimen 0DS0ZU from CCDI case PBCHAU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.3 years (5,603 days).
Specimen 0DS0ZU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bac0217-39a4-468c-916d-52b145098aa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS0Z9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f77ae7a7-2db5-428b-bb07-c7522fc5271b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 143/578 reads (25%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC7A10 | c.1468C>A p.L490M | Missense Mutation (SNP) | VAF 102/749 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF732 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 80/599 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- SLC7A10 | c.1467G>A p.E489= | Silent (SNP) | VAF 101/750 reads (13%) | called by muse, mutect2, varscan2
